Somatic mutation profile of tumor specimen BA2302D (aliquot aq-BA2302D) from BEATAML1.0 case 2336, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Therapy related myeloid neoplasm; Tissue or organ of origin: Bone marrow; Age at diagnosis: 78.4 years (28,636 days).
Specimen BA2302D: Sample type: Recurrent Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 10b17160-7bda-457c-9acb-39c8c9b94983.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2185D (Solid Tissue Normal), aliquot aq-BA2185D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/28ba12b2-bf88-4138-b01d-182faf9177dc

The open-access MAF lists 20 somatic variants for this specimen: 11 protein-altering or splice-affecting, 7 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 7, 3'UTR 1, 5'UTR 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 53/148 reads (36%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.03); PolyPhen benign (0.1); catalogued as rs121913499, CM1111831, COSV61615256, COSV61615456, COSV61615649; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ALPK2 | c.3256G>A p.V1086I | Missense Mutation (SNP) | VAF 52/114 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.3); catalogued as rs763412634; called by muse, mutect2, varscan2
- ARHGEF28 | c.5018C>T p.A1673V (on ENST00000426542; = p.A1699V on NM_001080479.2) | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT tolerated (0.54); PolyPhen benign (0.007); catalogued as rs1036472928, COSV99712789; called by mutect2, varscan2
- DGKI | c.2447C>T p.P816L | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT tolerated (0.35); PolyPhen benign (0.343); catalogued as rs1356488881; called by muse, mutect2, varscan2
- LTBP2 | c.2099G>A p.R700H | Missense Mutation (SNP) | VAF 76/145 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs750926855, COSV56212028; called by muse, mutect2, varscan2
- TSR1 | c.893A>C p.Q298P | Missense Mutation (SNP) | VAF 74/169 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.521); catalogued as rs763507991; called by muse, mutect2, varscan2
- CNR1 | c.341G>A p.S114N | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.306); called by muse, mutect2, varscan2
- GNAI2 | c.676G>T p.V226L | Missense Mutation (SNP) | VAF 43/97 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.308); called by muse, mutect2, varscan2
- GSPT2 | c.706G>T p.E236* | Nonsense Mutation (SNP) | VAF 85/195 reads (44%) | called by muse, mutect2, varscan2
- ITPR3 | c.4461C>A p.N1487K | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.421); called by muse, mutect2
- STAT2 | c.1813T>A p.S605T | Missense Mutation (SNP) | VAF 35/104 reads (34%) | SIFT tolerated (0.5); PolyPhen benign (0.003); called by muse, varscan2
- CPA3 | c.819G>A p.R273= | Silent (SNP) | VAF 94/229 reads (41%) | catalogued as COSV56045574, COSV56047000; called by muse, mutect2, varscan2
- CRYGN | c.174G>A p.R58= | Silent (SNP) | VAF 72/191 reads (38%) | called by muse, mutect2, varscan2
- DNAH1 | c.6963C>A p.G2321= | Silent (SNP) | VAF 4/32 reads (13%) | called by muse, mutect2
- ERLEC1 | c.1026T>C p.S342= | Silent (SNP) | VAF 77/200 reads (39%) | called by muse, mutect2, varscan2
- FN1 | c.2250C>T p.F750= | Silent (SNP) | VAF 11/262 reads (4%) | called by muse, mutect2
- FNDC3A | c.2283G>A p.Q761= (on ENST00000492622 / NM_001079673.2; = p.Q705= on NM_014923.5) | Silent (SNP) | VAF 29/60 reads (48%) | called by muse, varscan2
- GOLGB1 | c.5262A>G p.E1754= | Silent (SNP) | VAF 51/117 reads (44%) | called by muse, mutect2, varscan2
- AK2 | c.*1716C>T | 3'UTR (SNP) | VAF 39/82 reads (48%) | called by muse, mutect2, varscan2
- FARP1 | c.-1C>A | 5'UTR (SNP) | VAF 3/33 reads (9%) | called by muse, mutect2
